Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RJ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RJ-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

Collection Date:

- PART 1: LYMPH NODES, LEVEL 8, BIOPSY –**
THREE ANTHRACOTIC LYMPH NODES FREE OF TUMOR.
- PART 2: "GASTRIC TISSUE", BIOPSY –**
ADIPOSE TISSUE WITH NO PATHOLOGIC CHANGE.
- PART 3: LYMPH NODE, OMENTAL, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 4: LYMPH NODES, LEVEL 7, BIOPSY –**
THREE ANTHRACOTIC LYMPH NODES FREE OF TUMOR.
- PART 5: LYMPH NODE, LEVEL 11, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 6: "LYMPH NODE", NEAR THORACIC DUCT, BIOPSY –**
A. ADIPOSE TISSUE AND BLOOD VESSELS WITH NO PATHOLOGIC CHANGE.
B. NO LYMPH NODE PRESENT.
- PART 7: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY –**
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA WITH SIGNET RING CELLS OF GASTROESOPHAGEAL JUNCTION WITH EXTENSION INTO SUBMUCOSA (0.8 CM).
B. PROXIMAL (ESOPHAGEAL), DISTAL (GASTRIC), AND CIRCUMFERENTIAL RESECTION MARGINS ARE FREE OF TUMOR.
C. NO PERINEURAL OR ANGIOLYMPHATIC INVASION SEEN.
D. FIVE LYMPH NODES FREE OF TUMOR.
E. PATHOLOGIC STAGE: pT1bN0.
- PART 8: LYMPH NODE, SUBCARINAL, NEAR PULMONARY ARTERY, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 9: LYMPH NODE, SUBCARINAL, NEAR RIGHT MAIN BRONCHUS, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 10: GASTROESOPHAGEAL FAT, BIOPSY –**
A. TWO LYMPH NODES FREE OF TUMOR.
B. ADIPOSE TISSUE WITH NO PATHOLOGIC CHANGE.
- PART 11: LYMPH NODE, SUBCARINAL NEAR LEFT ATRIUM, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 12: LYMPH NODE, PROXIMAL PARAESOPHAGEAL, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 13: LYMPH NODE, SUBCARINAL ON ESOPHAGUS, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 14: LYMPH NODE, SUBCARINAL, LEFT MAIN BRONCHUS, BIOPSY –**
ONE ANTHRACOTIC LYMPH NODE FREE OF TUMOR.
- PART 15: LYMPH NODES, UPPER PARAESOPHAGEAL, BIOPSY –**
THREE ANTHRACOTIC LYMPH NODES FREE OF TUMOR.
- PART 16: ESOPHAGUS AND STOMACH, RINGS –**
SEGMENTS OF ESOPHAGUS AND STOMACH FREE OF TUMOR.
- PART 17: STOMACH, GASTRIC MARGIN –**
SEGMENT OF STOMACH FREE OF TUMOR AND LINED BY OXYNTIC MUCOSA.

Adenocarcinoma NOS
8/14/13
Site Gastroesophageal
junction C16.0
Jed 8/2/13

5% Signet ring, per TSS.

Bx

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS**

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Esophagogastric junction (EGJ) region (tumor involves EGJ and epicenter within 5cm of EGJ)
TUMOR SIZE: Greatest dimension: 0.8 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM)
pT1b
pN0
Number of lymph nodes examined: 24
Number of lymph nodes involved: 0
pM Not applicable
No prior treatment
PRIOR TREATMENT:
MARGINS
Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
ANGIOLYMPHATIC INVASION: Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified

COMPREHENSIVE THERANOSTIC SUMMARY

IN SITU HYBRIDIZATION / FISH:
HER2 (ERBB2) amplification:

RESULTS
NEGATIVE

****See Special Procedure reports below for additional details and background on
In situ/FISH and/or testing as pertinent****

SPECIAL PROCEDURES:**In Situ Procedure****Interpretation**

HER2 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

Cells Analyzed: 60

Ratio HER2/CEP17: 1.05

SNR: 2.6

CNR: 2.5

% Hyperdiploid: 30(50.0%)

Results**INTERPRETATION GUIDELINES AND PROBE INFORMATION:**

Probe: **HER2** DNA Probe

Probe Description: The **HER2** DNA probe is a 190 Kb directly labeled fluorescent DNA probe specific for the **HER2** gene locus. The CEP 17 DNA probe is a 5.4 Kb directly labeled fluorescent DNA probe specific for the alpha satellite DNA sequence at the centromeric region of chromosome 17. The probes are pre-mixed and pre-denatured in hybridization buffer.

Interpretation:

HER2 negative: HER2 gene/chromosome 17 ratio less than 2.0

HER2 positive: HER2 gene/chromosome 17 ratio greater than 2.0

Results should be considered along with other clinical information.

_____ has modified the suggested manufacturer protocol for HER2 FISH testing. The modifications have been tested and validated. The modifications are as follows: Slides are deparaffinized in _____ Tissue is digested in protease 31 minutes; Tissue and probe are co-denatured at 90 C for 12 minutes; Paraffin pretreatment reagents and control slides are prepared in house. Amplified, non-amplified, and internal (centromere 17) controls were used in the testing. The laboratory takes responsibility for the test performance.

FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the **HER2** and the **CEP17** probes.

Source: NCI Genomic Data Commons file 335e755d-72b0-4f32-a633-3680488260d1 (TCGA-IN-A6RJ.27CF1376-834D-47B5-AD17-040D9E558D8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).